Somatic mutation profile of tumor specimen MMRF_2379_1_BM_CD138pos (aliquot MMRF_2379_1_BM_CD138pos_T1_KHS5U_L11007) from MMRF case MMRF_2379, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.6 years (29,070 days).
Specimen MMRF_2379_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10c7aaba-9614-46a4-8a02-15a952b31d63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2379_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2379_1_PB_Whole_C2_KHS5U_L11008; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76d4f9aa-6154-4c8c-b49f-846489bf408f

The open-access MAF lists 167 somatic variants for this specimen: 80 protein-altering or splice-affecting, 21 silent, 66 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, 3'UTR 42, Silent 21, Intron 11, Nonsense Mutation 8, 5'UTR 7, Splice Site 5, 3'Flank 4, Frame Shift Ins 2, RNA 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 22/248 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 9/104 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, mutect2
- ADGRD2 | c.673G>A p.V225M | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1479974834; called by muse, mutect2, varscan2
- ANKRD50 | c.399G>T p.Q133H | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV72385098; called by muse, mutect2, varscan2
- BACH2 | c.1283G>A p.R428Q | Missense Mutation (SNP) | VAF 176/308 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs768854192, COSV57610512, COSV57611676; called by muse, mutect2, varscan2
- CHL1 | c.2319G>A p.M773I (on ENST00000397491 / NM_001253387.1; = p.M789I on NM_006614.4) | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as rs377255191; called by muse, mutect2, varscan2
- CNTN5 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54280074; called by muse, mutect2, varscan2
- CYP4F3 | c.369del p.F124Sfs*5 | Frame Shift Del (DEL) | VAF 58/205 reads (28%) | catalogued as COSV55409245; called by mutect2, pindel, varscan2
- ERBB4 | c.3187C>A p.Q1063K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.93); catalogued as COSV61483996, COSV61491924; called by muse, mutect2, varscan2
- GSDMA | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as rs375928728; called by muse, mutect2, varscan2
- IGHV2-70D | c.261G>C p.R87S | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as rs1415610196; called by muse, mutect2, varscan2
- IGLV3-1 | c.158G>A p.W53* | Nonsense Mutation (SNP) | VAF 54/61 reads (89%) | catalogued as rs567307194; called by muse, varscan2
- IGLV3-1 | c.159G>T p.W53C | Missense Mutation (SNP) | VAF 54/61 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs145290417; called by muse, varscan2
- LCE2A | c.253C>A p.P85T | Missense Mutation (SNP) | VAF 7/179 reads (4%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.046); catalogued as rs1292849145; called by muse, mutect2
- MAGOH | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs1475248030, COSV65161169, COSV65161325; called by muse, mutect2
- MKRN2OS | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 24/293 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.135); catalogued as rs755779364; called by muse, mutect2
- NES | c.2380G>C p.E794Q | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV63960401; called by muse, mutect2, varscan2
- PTPN21 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 58/59 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752428074; called by muse, mutect2, varscan2
- SBF1 | c.3095A>T p.H1032L | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs771969952; called by muse, mutect2, varscan2
- SEC24C | c.2110G>A p.V704M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.69); catalogued as rs1255327209; called by muse, mutect2, varscan2
- SLC23A2 | c.1313C>G p.S438C | Missense Mutation (SNP) | VAF 76/147 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57770776; called by muse, mutect2, varscan2
- TARM1 | c.166C>T p.R56* (on ENST00000616041 / NM_001330650.1; = p.R48* on NM_001135686.3) | Nonsense Mutation (SNP) | VAF 141/211 reads (67%) | catalogued as rs1335591843, COSV71524846; called by muse, mutect2, varscan2
- TMEM249 | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as rs1554852161; called by muse, mutect2
- TRIM60 | c.1247G>C p.G416A | Missense Mutation (SNP) | VAF 94/171 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61970901; called by muse, mutect2, varscan2
- UGT2A1 | c.1304+1G>A p.X435_splice | Splice Site (SNP) | VAF 27/57 reads (47%) | catalogued as rs369701259, COSV99683723; called by muse, mutect2, varscan2
- ZSCAN2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 62/215 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV59108497; called by muse, mutect2, varscan2
- ABL2 | c.346T>A p.Y116N (on ENST00000502732 / NM_007314.4; = p.Y101N on NM_005158.5) | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHRR | c.1562A>G p.D521G | Missense Mutation (SNP) | VAF 111/160 reads (69%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- AJAP1 | c.77G>A p.W26* | Nonsense Mutation (SNP) | VAF 86/210 reads (41%) | called by muse, mutect2, varscan2
- ANKUB1 | c.1004G>A p.G335E | Missense Mutation (SNP) | VAF 81/328 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ARHGAP26 | c.1664T>C p.I555T | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- BBS12 | c.766G>C p.V256L | Missense Mutation (SNP) | VAF 8/250 reads (3%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- BFSP2 | c.935A>G p.K312R | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CCDC180 | c.2491A>T p.K831* | Nonsense Mutation (SNP) | VAF 19/188 reads (10%) | called by muse, mutect2
- CSMD1 | c.8102A>G p.D2701G (on ENST00000520002; = p.D2700G on NM_033225.6) | Missense Mutation (SNP) | VAF 63/118 reads (53%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DCAF7 | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 56/132 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- EBNA1BP2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 63/124 reads (51%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- EMCN | c.140C>A p.S47* | Nonsense Mutation (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- EPS8L1 | c.2068C>G p.Q690E (on ENST00000201647 / NM_133180.3; = p.Q563E on NM_017729.3) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- EXOC3L2 | c.1416G>T p.E472D | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.968); called by muse, varscan2
- FNIP2 | c.1856A>C p.N619T | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- GAREM1 | c.432C>A p.Y144* | Nonsense Mutation (SNP) | VAF 30/213 reads (14%) | called by muse, mutect2, varscan2
- GASK1B | c.1105C>G p.L369V | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- GRIK2 | c.386A>C p.H129P | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IGHD | c.514C>G p.L172V | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- MEGF9 | c.1358-1G>C p.X453_splice | Splice Site (SNP) | VAF 75/119 reads (63%) | called by muse, mutect2, varscan2
- NAP1L4 | c.976C>T p.R326W | Missense Mutation (SNP) | VAF 107/225 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- NCKAP1 | c.1954A>C p.K652Q | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- NEB | c.14479C>A p.Q4827K | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR51F1 | c.382G>T p.A128S | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.666); called by muse, mutect2, varscan2
- PER1 | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 36/68 reads (53%) | called by muse, mutect2, varscan2
- PIP4P2 | c.455T>C p.V152A | Missense Mutation (SNP) | VAF 67/140 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PLK2 | c.1615C>T p.P539S | Missense Mutation (SNP) | VAF 57/181 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PPP1CB | c.914A>G p.Q305R | Missense Mutation (SNP) | VAF 17/272 reads (6%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2
- PRAMEF19 | c.740C>G p.P247R | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.071); called by muse, mutect2
- RAI2 | c.352G>A p.G118S | Missense Mutation (SNP) | VAF 64/65 reads (98%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- RFPL4AL1 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 130/468 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RGS1 | c.281-1G>A p.X94_splice | Splice Site (SNP) | VAF 34/74 reads (46%) | called by muse, mutect2, varscan2
- RPS24 | c.280-1G>T p.X94_splice | Splice Site (SNP) | VAF 4/9 reads (44%) | called by muse, mutect2, varscan2
- RYR2 | c.3381G>T p.E1127D | Missense Mutation (SNP) | VAF 65/133 reads (49%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SHISA7 | c.1070C>T p.T357M | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- SHROOM1 | c.488T>G p.L163R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- SLC16A14 | c.1303A>G p.I435V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- SPTLC2 | c.1414A>G p.M472V | Missense Mutation (SNP) | VAF 79/83 reads (95%) | SIFT deleterious (0.04); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- STXBP1 | c.1541C>G p.A514G | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); called by muse, mutect2, varscan2
- SVIL | c.3362C>T p.P1121L (on ENST00000355867 / NM_021738.3; = p.P695L on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/147 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SYT12 | c.1097T>G p.L366R | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TACC2 | c.5153C>A p.A1718E | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- TAS2R41 | c.689C>G p.T230S | Missense Mutation (SNP) | VAF 45/165 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- TBC1D8 | c.2935G>C p.D979H | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- TENT5C | c.527dup p.F177Vfs*2 | Frame Shift Ins (INS) | VAF 48/127 reads (38%) | called by mutect2, pindel, varscan2
- THSD1 | c.1093C>T p.R365* | Nonsense Mutation (SNP) | VAF 22/125 reads (18%) | called by muse, mutect2, varscan2
- TTLL5 | c.3164C>T p.T1055I | Missense Mutation (SNP) | VAF 36/38 reads (95%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.46817-1G>C p.X15606_splice (on ENST00000591111; = p.X8182_splice on NM_003319.4) | Splice Site (SNP) | VAF 7/108 reads (6%) | called by muse, mutect2
- U2SURP | c.2917G>C p.D973H | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- WDR76 | c.1189G>C p.E397Q | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- WDR83 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 16/167 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.031); called by muse, mutect2
- XIRP2 | c.6041A>C p.K2014T (on ENST00000628543; = p.K2189T on NM_152381.6) | Missense Mutation (SNP) | VAF 90/208 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- ZNF394 | c.1120_1121insAT p.F374Yfs*29 | Frame Shift Ins (INS) | VAF 152/415 reads (37%) | called by mutect2, pindel, varscan2
- ZNF483 | c.1873C>A p.H625N | Missense Mutation (SNP) | VAF 43/411 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABO | c.468C>T p.A156= | Silent (SNP) | VAF 65/286 reads (23%) | catalogued as rs782423915; called by muse, mutect2, varscan2
- APOB | c.2967C>T p.S989= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as rs773461882, COSV51924314; called by muse, mutect2, varscan2
- BAHCC1 | c.2841G>A p.K947= | Silent (SNP) | VAF 48/110 reads (44%) | catalogued as rs1339694117; called by muse, mutect2, varscan2
- BMP6 | c.1521A>T p.V507= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV51669337; called by muse, mutect2
- BNIPL | c.372C>T p.D124= | Silent (SNP) | VAF 25/185 reads (14%) | catalogued as rs144241818; called by muse, mutect2, varscan2
- CCDC27 | c.1791C>T p.S597= | Silent (SNP) | VAF 39/101 reads (39%) | catalogued as rs771091105; called by muse, mutect2, varscan2
- CDC37 | c.762C>T p.D254= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs773411962; called by muse, mutect2, varscan2
- CPAMD8 | c.2536C>T p.L846= (on ENST00000651564; = p.L799= on NM_015692.5) | Silent (SNP) | VAF 8/123 reads (7%) | called by muse, mutect2
- CREBBP | c.4575A>G p.Q1525= | Silent (SNP) | VAF 19/153 reads (12%) | called by muse, mutect2, varscan2
- DMC1 | c.693G>C p.V231= | Silent (SNP) | VAF 61/149 reads (41%) | called by muse, mutect2, varscan2
- GAL3ST1 | c.450C>T p.R150= | Silent (SNP) | VAF 97/209 reads (46%) | catalogued as rs749547797, COSV58891953; called by muse, mutect2, varscan2
- GPD1 | c.624C>A p.A208= | Silent (SNP) | VAF 22/95 reads (23%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.60C>G p.S20= | Silent (SNP) | VAF 62/76 reads (82%) | catalogued as rs577917177; called by muse, varscan2
- LPCAT1 | c.1209G>A p.E403= | Silent (SNP) | VAF 40/436 reads (9%) | catalogued as rs1285799091; called by muse, mutect2
- RNF13 | c.915G>A p.V305= | Silent (SNP) | VAF 33/327 reads (10%) | catalogued as rs1430076272; called by muse, mutect2, varscan2
- SF3A1 | c.1098G>A p.Q366= | Silent (SNP) | VAF 74/143 reads (52%) | catalogued as COSV99305695; called by muse, mutect2, varscan2
- TLN2 | c.6723G>A p.G2241= | Silent (SNP) | VAF 55/468 reads (12%) | called by muse, mutect2, varscan2
- TMEM201 | c.1326C>A p.P442= | Silent (SNP) | VAF 96/193 reads (50%) | called by muse, mutect2, varscan2
- TNKS | c.945G>T p.G315= | Silent (SNP) | VAF 29/108 reads (27%) | called by muse, mutect2, varscan2
- TSFM | c.15G>A p.R5= | Silent (SNP) | VAF 47/91 reads (52%) | catalogued as rs1411022509; called by muse, mutect2, varscan2
- ZBTB40 | c.2628C>A p.A876= | Silent (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- ADAMTS1 | c.-394C>T | 5'UTR (SNP) | VAF 59/130 reads (45%) | catalogued as rs1008894950; called by muse, mutect2, varscan2
- ALDH1A3 | c.1467-193del | Intron (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- ATP1B1 | c.*94A>T | 3'UTR (SNP) | VAF 21/42 reads (50%) | called by muse, mutect2, varscan2
- CASQ1 | c.*406G>A | 3'UTR (SNP) | VAF 63/130 reads (48%) | called by muse, mutect2, varscan2
- CATSPER2 | chr15:43629060 ins A | 3'Flank (INS) | VAF 138/517 reads (27%) | called by mutect2, pindel, varscan2
- CD27 | c.-71G>A | 5'UTR (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- CD28 | chr2:203706630 G>A | 5'Flank (SNP) | VAF 135/246 reads (55%) | called by muse, mutect2, varscan2
- CD44 | c.*993C>T | 3'UTR (SNP) | VAF 10/19 reads (53%) | catalogued as rs1317870581; called by muse, mutect2, varscan2
- CHD5 | c.*3562C>T | 3'UTR (SNP) | VAF 110/299 reads (37%) | called by muse, mutect2, varscan2
- CLDN17 | c.*124del | 3'UTR (DEL) | VAF 31/65 reads (48%) | called by mutect2, pindel, varscan2
- COBL | c.1096+2042G>A | Intron (SNP) | VAF 104/169 reads (62%) | catalogued as rs745397609; called by muse, mutect2, varscan2
- DBNL | c.*6665G>C | 3'UTR (SNP) | VAF 23/70 reads (33%) | catalogued as rs1306236986; called by muse, mutect2, varscan2
- DFFA | c.*1765dup | 3'UTR (INS) | VAF 4/29 reads (14%) | catalogued as rs150560352; called by pindel, varscan2
- EIF2AK2 | c.*549A>C | 3'UTR (SNP) | VAF 5/12 reads (42%) | called by muse, mutect2, varscan2
- EPHB1 | c.-1G>A | 5'UTR (SNP) | VAF 87/337 reads (26%) | catalogued as COSV67672768; called by muse, mutect2, varscan2
- EYS | c.1766+3510G>C | Intron (SNP) | VAF 8/37 reads (22%) | called by muse, mutect2, varscan2
- FARP1 | c.2274+316G>C | Intron (SNP) | VAF 65/97 reads (67%) | called by muse, mutect2, varscan2
- FAT3 | c.*3175A>C | 3'UTR (SNP) | VAF 39/82 reads (48%) | called by muse, mutect2, varscan2
- FUBP3 | c.*992T>A | 3'UTR (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- GAB2 | c.*2714C>T | 3'UTR (SNP) | VAF 12/158 reads (8%) | catalogued as rs561969906; called by muse, mutect2
- GATA4 | chr8:11761919 G>C | 3'Flank (SNP) | VAF 124/258 reads (48%) | called by muse, mutect2, varscan2
- GJB7 | c.*418A>C | 3'UTR (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- GSG1L | c.*289G>A | 3'UTR (SNP) | VAF 60/122 reads (49%) | catalogued as rs1402027300; called by muse, mutect2, varscan2
- HIPK3 | c.*350A>G | 3'UTR (SNP) | VAF 11/72 reads (15%) | catalogued as rs879373218; called by muse, mutect2, varscan2
- HNRNPH1 | c.*1-86T>G | Intron (SNP) | VAF 22/43 reads (51%) | called by muse, varscan2
- KCNJ3 | c.*174G>A | 3'UTR (SNP) | VAF 24/51 reads (47%) | catalogued as rs1002893650; called by muse, mutect2, varscan2
- KIF3B | c.*3127C>T | 3'UTR (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- KIF5A | c.*10C>T | 3'UTR (SNP) | VAF 22/248 reads (9%) | catalogued as rs779328230; called by muse, mutect2
- LGR4 | c.*1440T>G | 3'UTR (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- LILRB4 | c.-12G>A | 5'UTR (SNP) | VAF 58/185 reads (31%) | catalogued as rs201956451; called by muse, mutect2, varscan2
- LRRC15 | c.*1586C>A | 3'UTR (SNP) | VAF 46/170 reads (27%) | called by muse, mutect2, varscan2
- MMP16 | c.-83dup | 5'UTR (INS) | VAF 40/90 reads (44%) | catalogued as rs1357599418; called by mutect2, varscan2
- MRAS | c.448-55A>G | Intron (SNP) | VAF 31/126 reads (25%) | called by muse, mutect2, varscan2
- MTSS1 | c.*1678C>T | 3'UTR (SNP) | VAF 6/68 reads (9%) | called by muse, mutect2
- NOC2LP2 | n.564C>T | RNA (SNP) | VAF 63/137 reads (46%) | catalogued as rs996807598; called by muse, mutect2, varscan2
- NOS1 | c.*5741C>T | 3'UTR (SNP) | VAF 22/118 reads (19%) | called by muse, mutect2, varscan2
- NPR3 | c.*3842G>A | 3'UTR (SNP) | VAF 32/96 reads (33%) | catalogued as rs904444164; called by muse, mutect2, varscan2
- NRXN1 | c.-622T>A | 5'UTR (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- NUDT16L1 | c.*623G>A | 3'UTR (SNP) | VAF 7/61 reads (11%) | catalogued as rs1014588517; called by muse, mutect2, varscan2
- OR9I1 | c.*27A>G | 3'UTR (SNP) | VAF 127/226 reads (56%) | catalogued as rs913769776; called by muse, mutect2, varscan2
- PAX7 | c.-57G>A | 5'UTR (SNP) | VAF 104/213 reads (49%) | called by muse, mutect2, varscan2
- PCSK7 | c.860+49C>T | Intron (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2
- PELI1 | c.*251_*252del | 3'UTR (DEL) | VAF 21/50 reads (42%) | catalogued as rs1183040219; called by mutect2, pindel, varscan2
- PIK3C3 | c.*2335A>C | 3'UTR (SNP) | VAF 33/58 reads (57%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.*6383C>T | 3'UTR (SNP) | VAF 10/122 reads (8%) | called by muse, mutect2
- PPP1R10 | c.*572T>C | 3'UTR (SNP) | VAF 32/85 reads (38%) | called by muse, mutect2, varscan2
- PTPRG | c.*2012del | 3'UTR (DEL) | VAF 28/100 reads (28%) | catalogued as rs1481185897; called by mutect2, pindel, varscan2
- RALGAPB | c.*262A>G | 3'UTR (SNP) | VAF 21/57 reads (37%) | catalogued as rs1351748326; called by muse, mutect2, varscan2
- RALGPS1 | c.*3105C>G | 3'UTR (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- SAA1 | c.*44C>G | 3'UTR (SNP) | VAF 13/38 reads (34%) | called by muse, mutect2, varscan2
- SLC29A2 | c.1260-275G>A | Intron (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
- SLC35F3 | c.*102C>G | 3'UTR (SNP) | VAF 42/92 reads (46%) | called by muse, mutect2, varscan2
- SREK1 | c.1233-63G>T | Intron (SNP) | VAF 16/54 reads (30%) | catalogued as rs1342764618; called by muse, varscan2
- TLN2 | c.*3232C>T | 3'UTR (SNP) | VAF 58/162 reads (36%) | catalogued as rs903137105; called by muse, mutect2, varscan2
- TMEFF2 | c.439+207C>G | Intron (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- TMEM18 | c.57+536C>G | Intron (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- TMEM223 | chr11:62787652 G>A | 3'Flank (SNP) | VAF 37/99 reads (37%) | catalogued as rs1452004194, COSV53668330; called by muse, mutect2, varscan2
- TRAF1 | c.*2588T>A | 3'UTR (SNP) | VAF 25/36 reads (69%) | called by muse, mutect2, varscan2
- TRPM3 | chr9:70535903 G>A | 3'Flank (SNP) | VAF 166/734 reads (23%) | catalogued as COSV100676511, COSV62583704; called by muse, mutect2, varscan2
- TSSK1B | c.*23A>T | 3'UTR (SNP) | VAF 114/341 reads (33%) | called by muse, mutect2, varscan2
- TTL | c.*2382T>G | 3'UTR (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- TUSC3 | c.*393G>T | 3'UTR (SNP) | VAF 30/67 reads (45%) | called by muse, mutect2, varscan2
- UACA | c.*2219A>G | 3'UTR (SNP) | VAF 34/92 reads (37%) | called by muse, mutect2, varscan2
- WIPF3 | c.*537C>T | 3'UTR (SNP) | VAF 23/43 reads (53%) | catalogued as rs1429807970; called by muse, mutect2, varscan2
- XKR4 | c.*93G>T | 3'UTR (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- ZNF652 | c.*1027T>A | 3'UTR (SNP) | VAF 10/81 reads (12%) | called by muse, mutect2, varscan2
